Somatic mutation profile of tumor specimen ALCH-B4X0-TTP1-A (aliquot ALCH-B4X0-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4X0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.0 years (18,641 days).
Specimen ALCH-B4X0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4312f97-b93d-42fc-984e-e8d0172dc43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4X0-NB1-A (Blood Derived Normal), aliquot ALCH-B4X0-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82277884-87e8-4fb4-a71f-de72b52b69d3

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, 5'UTR 2, Intron 2, RNA 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELF3 | c.1214A>C p.H405P | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs367603038; called by muse, mutect2, varscan2
- CHRNA4 | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs201645533; called by muse, mutect2
- MAGI2 | c.3739G>A p.A1247T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs555798505, COSV62676473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RENBP | c.669G>C p.R223S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV100129826; called by muse, mutect2
- SLC26A4 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128475; called by muse, mutect2
- SMAD4 | c.1526G>A p.W509* | Nonsense Mutation (SNP) | VAF 56/616 reads (9%) | catalogued as COSV61687596; called by muse, mutect2
- ZBTB46 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV55506542; called by muse, mutect2
- BORA | c.1489C>G p.Q497E (on ENST00000613797; = p.Q422E on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRD8 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2
- FAM71F2 | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 27/408 reads (7%) | called by muse, mutect2
- GTF3C1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 31/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- KMT2A | c.7454A>G p.D2485G | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2
- PHKA2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 40/709 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- PPEF2 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2
- STARD8 | c.2969A>T p.D990V | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- NEIL3 | c.1356A>G p.T452= | Silent (SNP) | VAF 46/470 reads (10%) | called by muse, mutect2
- POM121L2 | c.2664T>A p.P888= | Silent (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- TGFBR1 | c.469C>A p.R157= | Silent (SNP) | VAF 44/630 reads (7%) | catalogued as COSV66624800; called by muse, mutect2
- VWF | c.1920C>A p.V640= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- ZBTB46 | c.684C>T p.I228= | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- EIF3L | c.-5C>T | 5'UTR (SNP) | VAF 13/97 reads (13%) | catalogued as rs745650688, COSV66045723; called by muse, mutect2, varscan2
- IQCF5 | c.-47C>A | 5'UTR (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- LINC02520 | n.385C>G | RNA (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- RHOF | chr12:121797564 G>C | 5'Flank (SNP) | VAF 45/393 reads (11%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1648-10C>T | Intron (SNP) | VAF 13/120 reads (11%) | catalogued as rs748611208; called by muse, mutect2, varscan2
- SLITRK5 | c.-9+763T>A | Intron (SNP) | VAF 16/474 reads (3%) | called by muse, mutect2
- SNORD114-21 | n.26G>A | RNA (SNP) | VAF 109/439 reads (25%) | catalogued as rs773496538; called by muse, mutect2, varscan2
